Somatic mutation profile of tumor specimen TARGET-20-PASLPU-09A (aliquot TARGET-20-PASLPU-09A-01D) from TARGET case TARGET-20-PASLPU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,524 days).
Specimen TARGET-20-PASLPU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 666bc381-daab-4a18-a071-c08339c294e1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLPU-14A (Bone Marrow Normal), aliquot TARGET-20-PASLPU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f2d445-0e9f-4639-a388-0a12a9ae9839

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1676T>A p.V559D | Missense Mutation (SNP) | VAF 93/205 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121913517, CM013551, COSV55386973, COSV55388782, COSV55393324; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.3846_3847insGG p.C1283Gfs*31 | Frame Shift Ins (INS) | VAF 61/175 reads (35%) | called by mutect2, pindel, varscan2
- ODF1 | c.325A>C p.R109= | Silent (SNP) | VAF 74/165 reads (45%) | called by muse, mutect2, varscan2
